Somatic mutation profile of tumor specimen TCGA-EL-A3CS-01A (aliquot TCGA-EL-A3CS-01A-21D-A19J-08) from TCGA case TCGA-EL-A3CS, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 63.0 years (22,993 days).
Specimen TCGA-EL-A3CS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f40d258e-f545-4d37-b7e5-36b1b1d95e70.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3CS-10A (Blood Derived Normal), aliquot TCGA-EL-A3CS-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b63a5360-0d00-4b07-a11b-306a9b244011

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 4, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNHD1 | c.11629A>C p.S3877R | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV54431975; called by muse, mutect2
- E4F1 | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs761050026, COSV100066076, COSV57039450; called by muse, mutect2
- GRIK2 | c.1508G>A p.R503H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as rs778431133, COSV59718340; called by muse, mutect2, varscan2
- HNF4A | c.1142A>T p.D381V | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV57380663; called by mutect2, varscan2
- IL18RAP | c.808A>C p.T270P | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.773); catalogued as COSV51824353; called by muse, mutect2, varscan2
- NUP133 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV54569085; called by muse, mutect2, varscan2
- RPRD1A | c.94C>G p.H32D | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV59821542; called by muse, mutect2, varscan2
- XRCC5 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV67535196; called by muse, mutect2, varscan2
- ADAM21 | c.207C>A p.G69= | Silent (SNP) | VAF 22/192 reads (11%) | catalogued as rs1254329803, COSV50789540; called by muse, mutect2, varscan2
- C12orf40 | c.1200C>T p.S400= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as rs1457523150, COSV61130162; called by muse, mutect2, varscan2
- HP | c.33G>A p.L11= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as COSV63325741; called by muse, mutect2, varscan2
- JMJD1C | c.2241C>A p.T747= | Silent (SNP) | VAF 30/78 reads (38%) | catalogued as COSV67858980; called by muse, mutect2, varscan2
- TTN | c.10360+5384T>C | Intron (SNP) | VAF 10/45 reads (22%) | catalogued as COSV59935470; called by muse, mutect2, varscan2
